Somatic mutation profile of tumor specimen TARGET-40-NAAHBS-01A (aliquot TARGET-40-NAAHBS-01A-01D) from TARGET case TARGET-40-NAAHBS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.4 years (3,815 days).
Specimen TARGET-40-NAAHBS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbdbf9b5-50a8-4fc1-8ce0-8ddd28cf8176.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHBS-10A (Blood Derived Normal), aliquot TARGET-40-NAAHBS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/651e75d1-27aa-4377-a368-8310e8991de1

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITPR2 | c.7276G>A p.D2426N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV67266853; called by muse, mutect2, varscan2
- MUC4 | c.5528T>A p.V1843D | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as rs1220308531; called by muse, mutect2
- PCIF1 | c.1924C>T p.L642F | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- RPL10L | c.392T>A p.I131N | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
